Somatic mutation profile of tumor specimen TCGA-HW-A5KK-01A (aliquot TCGA-HW-A5KK-01A-11D-A27K-08) from TCGA case TCGA-HW-A5KK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 64.3 years (23,484 days).
Specimen TCGA-HW-A5KK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b84d6b1-3c60-4dee-974d-b463b41377f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-A5KK-10A (Blood Derived Normal), aliquot TCGA-HW-A5KK-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/062c978f-1824-4daf-ad6c-d2159e170f60

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Intron 3, Nonsense Mutation 2, Frame Shift Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1009T>C p.S337P | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV58642572; called by muse, mutect2, varscan2
- AMER3 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as rs1388329583, COSV58466362; called by muse, mutect2, varscan2
- CACNA1E | c.3844G>A p.V1282I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs1331568050, COSV62391649; called by mutect2, varscan2
- CDK13 | c.2725A>G p.T909A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV51699090; called by muse, mutect2, varscan2
- CELSR3 | c.9004C>T p.R3002W | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs760431521, COSV50851757; called by muse, mutect2, varscan2
- COPB2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1329164747, COSV60812415; called by muse, mutect2, varscan2
- DNAJB14 | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV62032642; called by muse, mutect2, varscan2
- EHD2 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as rs751209627, COSV54408023; called by muse, mutect2, varscan2
- GSDMD | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV52797050; called by muse, mutect2, varscan2
- LRRC37B | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV58951996; called by muse, mutect2, varscan2
- MAP7 | c.319A>T p.K107* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | catalogued as COSV63419120; called by muse, mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by muse, mutect2, varscan2
- PGAP1 | c.2340T>C p.N780= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100697959; called by muse, mutect2
- PKHD1 | c.3316T>A p.L1106I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); catalogued as COSV100580895; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2, varscan2
- PRB3 | c.847C>T p.P283S (on ENST00000381842; = p.P325S on NM_006249.5) | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.51); catalogued as rs1183714950, COSV54389425; called by muse, mutect2, varscan2
- SERPINB2 | c.830C>G p.T277S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100208147, COSV100208563; called by muse, mutect2
- SLC24A2 | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53863426; called by muse, mutect2, varscan2
- SPRYD3 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56853529; called by muse, mutect2, varscan2
- VAMP5 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs745868707, COSV60498264; called by muse, mutect2, varscan2
- VDAC3 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV50081239, COSV50081418; called by muse, mutect2, varscan2
- YTHDF1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV64832723; called by muse, mutect2, varscan2
- ZNF426 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV53469023; called by muse, mutect2, varscan2
- ZNF521 | c.1913A>C p.Q638P | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64126065; called by muse, mutect2, varscan2
- BMPR1B | c.507del p.Y169* | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- ELL2 | c.1508_1512del p.S503Kfs*7 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.1368C>T p.S456= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as COSV54503194; called by muse, mutect2, varscan2
- ATP10B | c.1689C>A p.T563= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV59149811; called by muse, mutect2, varscan2
- CEP250 | c.987T>C p.S329= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV61169604; called by muse, mutect2, varscan2
- GSDMD | c.1449C>A p.P483= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV52797058; called by muse, mutect2, varscan2
- NAV2 | c.2457C>T p.D819= (on ENST00000396087 / NM_001244963.2; = p.D796= on NM_145117.5) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs771328189, COSV62321203; called by muse, mutect2, varscan2
- SYNE1 | c.14172G>A p.A4724= (on ENST00000367255 / NM_182961.4; = p.A4653= on NM_033071.3) | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs200419328, COSV54965826, COSV55069486; called by muse, mutect2, varscan2
- AC024940.1 | n.3767T>C | RNA (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.74C>A | RNA (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11320A>G | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57118608; called by muse, mutect2, varscan2
- RAC2 | c.107+487G>A | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs767222826, COSV50774131; called by muse, mutect2
- RARB | c.179-32306A>G | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs768498439, COSV100412103; called by muse, mutect2, varscan2
